Somatic mutation profile of tumor specimen TCGA-CM-6164-01A (aliquot TCGA-CM-6164-01A-11D-1650-10) from TCGA case TCGA-CM-6164, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Sigmoid colon; AJCC pathologic stage: Stage IIA; Age at diagnosis: 46.0 years (16,802 days).
Specimen TCGA-CM-6164-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4b227edc-8397-45e3-99b1-09bd70454d45.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CM-6164-10A (Blood Derived Normal), aliquot TCGA-CM-6164-10A-01D-1650-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4ddd32d8-63a5-47d9-90dc-0af2c57c4f2c

The open-access MAF lists 79 somatic variants for this specimen: 59 protein-altering or splice-affecting, 19 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 51, Silent 19, Nonsense Mutation 5, In Frame Del 1, Frame Shift Del 1, Intron 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.694C>T p.R232* | Nonsense Mutation (SNP) | VAF 121/333 reads (36%) | hotspot (GDC flag); catalogued as rs397515734, CM920029, COSV57320753; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KRAS | c.101C>T p.P34L | Missense Mutation (SNP) | VAF 33/196 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs104894366, CM061081, CM070967, CM070968, COSV55580791, COSV55588721, COSV56171292; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.797G>T p.G266V | Missense Mutation (SNP) | VAF 18/47 reads (38%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs193920774, CM1414506, COSV52664019, COSV52666760, COSV53585299; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- ABCA13 | c.4462A>G p.I1488V | Missense Mutation (SNP) | VAF 73/237 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.084); catalogued as COSV101330123; called by muse, varscan2
- ABCA13 | c.7838A>T p.D2613V | Missense Mutation (SNP) | VAF 36/161 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as COSV71284685, COSV71291603; called by muse, mutect2, varscan2
- ABCC1 | c.2581G>A p.A861T | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as rs45517537, COSV60681773; called by muse, mutect2, varscan2
- ABI3BP | c.473T>A p.I158N | Missense Mutation (SNP) | VAF 25/324 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); catalogued as COSV52531074; called by muse, mutect2
- APBA2 | c.640C>T p.R214C | Missense Mutation (SNP) | VAF 24/91 reads (26%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.402); catalogued as rs148979602; called by muse, mutect2, varscan2
- ARHGEF18 | c.1478C>T p.S493L (on ENST00000359920 / NM_001130955.2; = p.S389L on NM_015318.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 41/122 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs765235100, COSV60468020; called by muse, mutect2, varscan2
- ASXL1 | c.1774C>T p.Q592* | Nonsense Mutation (SNP) | VAF 62/210 reads (30%) | catalogued as rs951716574, COSV60102519; called by muse, mutect2, varscan2
- BSN | c.8875C>T p.R2959C | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1323972328, COSV56513757; called by muse, mutect2
- C11orf42 | c.337A>G p.T113A | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT tolerated (0.18); PolyPhen benign (0.037); catalogued as COSV56410186; called by muse, mutect2, varscan2
- C1orf146 | c.26T>C p.I9T | Missense Mutation (SNP) | VAF 115/328 reads (35%) | SIFT tolerated (0.77); PolyPhen benign (0); catalogued as COSV64880183; called by muse, mutect2, varscan2
- CD200R1 | c.359G>A p.R120H (on ENST00000471858 / NM_170780.3; = p.R143H on NM_138806.4) | Missense Mutation (SNP) | VAF 158/630 reads (25%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as rs144544564; called by muse, varscan2
- CNGA1 | c.826C>T p.R276C | Missense Mutation (SNP) | VAF 54/188 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs367772790, COSV62054132; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COL3A1 | c.1835G>T p.G612V | Missense Mutation (SNP) | VAF 63/174 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM119021, COSV58584144; called by muse, mutect2, varscan2
- DCHS1 | c.9043G>T p.A3015S | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT tolerated (0.32); PolyPhen benign (0.001); catalogued as rs867539218, COSV54996505; called by muse, mutect2, varscan2
- DPY19L2 | c.1288G>T p.G430C | Missense Mutation (SNP) | VAF 56/358 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.16); catalogued as COSV60541989; called by muse, mutect2, varscan2
- DUSP29 | c.217C>T p.R73C | Missense Mutation (SNP) | VAF 4/9 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.135); catalogued as rs776538597, COSV58300187, COSV58300610; called by muse, mutect2, varscan2
- ECM2 | c.1865C>G p.S622C | Missense Mutation (SNP) | VAF 31/214 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.076); catalogued as COSV60738942; called by muse, mutect2, varscan2
- FAM120C | c.2669G>A p.R890K | Missense Mutation (SNP) | VAF 76/311 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.093); catalogued as COSV60258130; called by muse, mutect2, varscan2
- FAM168B | c.10G>A p.V4I | Missense Mutation (SNP) | VAF 34/394 reads (9%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.007); catalogued as COSV66303755; called by muse, mutect2
- FAM83B | c.2960G>A p.R987H | Missense Mutation (SNP) | VAF 32/142 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs759117235, COSV60920258; called by muse, mutect2, varscan2
- FER1L6 | c.616G>A p.V206I | Missense Mutation (SNP) | VAF 53/183 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.061); catalogued as rs1305320085, COSV67548760; called by muse, mutect2, varscan2
- FLG | c.3235G>T p.E1079* | Nonsense Mutation (SNP) | VAF 27/187 reads (14%) | catalogued as COSV64238586; called by muse, mutect2, varscan2
- FSHR | c.176G>A p.R59Q | Missense Mutation (SNP) | VAF 30/88 reads (34%) | SIFT tolerated (0.25); PolyPhen benign (0.001); catalogued as rs867447724, COSV58619761; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- HRNR | c.1639C>T p.R547* | Nonsense Mutation (SNP) | VAF 35/137 reads (26%) | catalogued as rs142288299; called by muse, mutect2, varscan2
- IL1RAPL1 | c.493C>A p.R165S | Missense Mutation (SNP) | VAF 34/259 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.055); catalogued as COSV100149498, COSV56245289; called by muse, mutect2, varscan2
- KIT | c.548G>C p.C183S | Missense Mutation (SNP) | VAF 33/124 reads (27%) | SIFT tolerated (0.05); PolyPhen benign (0.151); catalogued as COSV99078462; called by muse, mutect2, varscan2
- LHPP | c.134G>A p.R45H | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.009); catalogued as rs202090877, COSV64328929; called by muse, mutect2, varscan2
- LRRK1 | c.1334C>A p.A445D | Missense Mutation (SNP) | VAF 18/118 reads (15%) | SIFT tolerated (0.24); PolyPhen benign (0.022); catalogued as COSV52604993; called by muse, mutect2, varscan2
- MAP10 | c.1438_1440del p.P480del | In Frame Del (DEL) | VAF 10/100 reads (10%) | catalogued as rs765072281; called by mutect2, pindel, varscan2
- MKLN1 | c.1199T>C p.M400T | Missense Mutation (SNP) | VAF 82/270 reads (30%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1259383967, COSV61760246; called by muse, mutect2
- MUC6 | c.536T>G p.F179C | Missense Mutation (SNP) | VAF 24/61 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV70136841; called by muse, mutect2, varscan2
- MXD3 | c.148dup p.Q50Pfs*15 | Frame Shift Ins (INS) | VAF 12/35 reads (34%) | catalogued as rs866699857; called by mutect2, varscan2
- NAP1L3 | c.587C>A p.P196H | Missense Mutation (SNP) | VAF 30/440 reads (7%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.573); catalogued as COSV100220531; called by muse, mutect2
- NBL1 | c.299C>T p.P100L | Missense Mutation (SNP) | VAF 11/109 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs750974701, COSV57029488, COSV57029691; called by muse, mutect2, varscan2
- NCKAP5 | c.2311C>A p.Q771K | Missense Mutation (SNP) | VAF 49/298 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.21); catalogued as COSV100493510; called by muse, mutect2, varscan2
- NEXMIF | c.3887T>C p.M1296T | Missense Mutation (SNP) | VAF 30/136 reads (22%) | SIFT tolerated, low confidence (0.67); PolyPhen benign (0); catalogued as COSV50023841; called by muse, mutect2
- NYAP2 | c.1385C>T p.S462L | Missense Mutation (SNP) | VAF 37/101 reads (37%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as rs865814391, COSV56000740; called by muse, mutect2, varscan2
- OR5V1 | c.218A>T p.Y73F | Missense Mutation (SNP) | VAF 71/152 reads (47%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.575); catalogued as COSV65826862; called by muse, mutect2, varscan2
- PCOLCE2 | c.1169del p.I390Tfs*8 | Frame Shift Del (DEL) | VAF 44/191 reads (23%) | catalogued as COSV55998044; called by mutect2, pindel, varscan2
- PHF20 | c.1383A>T p.K461N | Missense Mutation (SNP) | VAF 112/508 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.69); catalogued as COSV100180530; called by muse, mutect2, varscan2
- PLIN4 | c.724G>A p.G242S (on ENST00000301286; = p.G257S on NM_001367868.2) | Missense Mutation (SNP) | VAF 32/293 reads (11%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.87); catalogued as rs768859297, COSV56697245; called by muse, varscan2
- PTPMT1 | c.343G>A p.V115I | Missense Mutation (SNP) | VAF 12/126 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs376762868; called by muse, mutect2
- PTPRZ1 | c.1834G>A p.E612K | Missense Mutation (SNP) | VAF 12/109 reads (11%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.125); catalogued as rs1469276203, COSV66432630; called by muse, mutect2, varscan2
- RBP3 | c.1777G>A p.V593M | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as rs782377821; called by muse, varscan2
- RTL8B | c.182A>G p.D61G | Missense Mutation (SNP) | VAF 16/296 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101195629; called by muse, mutect2
- SHROOM4 | c.2695G>T p.D899Y | Missense Mutation (SNP) | VAF 28/327 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV56786205; called by muse, mutect2
- SLC41A2 | c.448A>G p.K150E | Missense Mutation (SNP) | VAF 57/296 reads (19%) | SIFT tolerated (0.38); PolyPhen benign (0.003); catalogued as COSV51603026; called by muse, mutect2, varscan2
- SPTBN1 | c.2515C>T p.R839W | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.925); catalogued as rs749069838, COSV61686578; called by muse, mutect2, varscan2
- TINAGL1 | c.842T>C p.F281S | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as COSV99593023; called by muse, mutect2, varscan2
- TMEM41B | c.865A>T p.K289* | Nonsense Mutation (SNP) | VAF 76/264 reads (29%) | catalogued as COSV55154703; called by muse, mutect2, varscan2
- TRIM60 | c.568A>G p.I190V | Missense Mutation (SNP) | VAF 20/117 reads (17%) | SIFT tolerated (0.62); PolyPhen benign (0.001); catalogued as rs767691084, COSV61970048; called by muse, mutect2, varscan2
- WFDC5 | c.295G>A p.D99N | Missense Mutation (SNP) | VAF 18/143 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57216687; called by muse, mutect2, varscan2
- WNT9A | c.505G>A p.G169R | Missense Mutation (SNP) | VAF 29/167 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1289226577, COSV55293697; called by muse, mutect2, varscan2
- ZNF804B | c.1642T>C p.F548L | Missense Mutation (SNP) | VAF 77/238 reads (32%) | SIFT tolerated (0.47); PolyPhen benign (0.009); catalogued as COSV60820448, COSV60830216; called by muse, mutect2, varscan2
- ZNF831 | c.4000C>T p.P1334S | Missense Mutation (SNP) | VAF 35/154 reads (23%) | SIFT tolerated (0.41); PolyPhen benign (0.023); catalogued as rs1397413367, COSV64038382; called by muse, mutect2, varscan2
- SSU72P8 | c.332G>T p.C111F | Missense Mutation (SNP) | VAF 14/166 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- ATP2B3 | c.1725C>T p.T575= | Silent (SNP) | VAF 16/159 reads (10%) | catalogued as COSV54842657, COSV99684307; called by muse, mutect2
- AWAT1 | c.372G>A p.S124= | Silent (SNP) | VAF 54/229 reads (24%) | catalogued as rs138134361, COSV100997223; called by muse, mutect2, varscan2
- BRWD3 | c.4167A>G p.E1389= | Silent (SNP) | VAF 133/305 reads (44%) | catalogued as rs751192224, COSV64745344; called by muse, mutect2, varscan2
- CACNA1A | c.117C>T p.G39= | Silent (SNP) | VAF 4/19 reads (21%) | catalogued as rs374304094; ClinVar: likely benign; called by mutect2, varscan2
- CSNK1A1L | c.957C>T p.A319= | Silent (SNP) | VAF 145/530 reads (27%) | catalogued as COSV65789460; called by muse, mutect2, varscan2
- DCAF12L1 | c.630C>T p.S210= | Silent (SNP) | VAF 20/95 reads (21%) | catalogued as COSV100948382, COSV64422747; called by muse, varscan2
- DMD | c.5749C>A p.R1917= | Silent (SNP) | VAF 20/169 reads (12%) | catalogued as rs763893272, COSV63741502; called by muse, mutect2, varscan2
- DST | c.15270G>A p.S5090= (on ENST00000361203 / NM_001374722.1; = p.S2678= on NM_015548.5) | Silent (SNP) | VAF 19/133 reads (14%) | catalogued as rs371189011, COSV55003403; called by muse, mutect2, varscan2
- FAM193A | c.2289G>A p.E763= | Silent (SNP) | VAF 23/53 reads (43%) | catalogued as COSV61192097; called by muse, mutect2, varscan2
- HOXA3 | c.1098C>T p.F366= | Silent (SNP) | VAF 6/66 reads (9%) | catalogued as COSV57828688; called by muse, mutect2
- KIF12 | c.1746G>A p.T582= (on ENST00000640217; = p.T444= on NM_138424.1) | Silent (SNP) | VAF 20/60 reads (33%) | catalogued as rs763582505, COSV65116886; called by muse, varscan2
- PARP14 | c.819A>G p.E273= | Silent (SNP) | VAF 51/181 reads (28%) | catalogued as COSV71734267; called by muse, mutect2, varscan2
- PCDH9 | c.1335G>A p.G445= | Silent (SNP) | VAF 49/203 reads (24%) | catalogued as COSV60529118; called by muse, mutect2, varscan2
- PCDHGA10 | c.72C>T p.F24= | Silent (SNP) | VAF 21/109 reads (19%) | catalogued as rs1168509242, COSV53915260; called by muse, mutect2, varscan2
- PDZD4 | c.792C>T p.P264= | Silent (SNP) | VAF 30/114 reads (26%) | catalogued as COSV99381539; called by muse, mutect2, varscan2
- PLPP1 | c.172T>C p.L58= | Silent (SNP) | VAF 60/134 reads (45%) | catalogued as COSV53304064; called by muse, mutect2, varscan2
- SNTG1 | c.1122G>A p.L374= | Silent (SNP) | VAF 8/74 reads (11%) | catalogued as COSV52431611; called by muse, mutect2, varscan2
- TENM4 | c.6897C>T p.R2299= | Silent (SNP) | VAF 24/73 reads (33%) | catalogued as rs775901315, COSV53615634, COSV99573207; called by muse, mutect2, varscan2
- TFRC | c.471T>C p.A157= | Silent (SNP) | VAF 83/274 reads (30%) | catalogued as COSV64054175; called by muse, mutect2
- CLCN3 | c.2367-2051G>A | Intron (SNP) | VAF 57/322 reads (18%) | catalogued as rs1229159383, COSV100641780; called by mutect2, varscan2
